Somatic mutation profile of tumor specimen ALCH-B4EQ-TTP1-A (aliquot ALCH-B4EQ-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4EQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.4 years (28,287 days).
Specimen ALCH-B4EQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2847406-76d3-498f-ac1f-8e44cbc73723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4EQ-NB1-A (Blood Derived Normal), aliquot ALCH-B4EQ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9bc592c-cc52-412f-820b-6c3ce18dae2f

The open-access MAF lists 30 somatic variants for this specimen: 14 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 11, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.12323G>A p.R4108Q | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs368532934; ClinVar: uncertain significance; called by muse, mutect2
- EDRF1 | c.2611G>T p.A871S (on ENST00000356792 / NM_001202438.2; = p.A837S on NM_015608.2) | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as COSV61762959; called by muse, mutect2
- FGD5 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs750545408, COSV53236523; called by muse, mutect2, varscan2
- HAP1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1555589586; called by muse, mutect2, varscan2
- HIRA | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as rs1360643171, COSV54276087; called by muse, mutect2
- SOWAHA | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV66332585; called by muse, mutect2
- EPM2AIP1 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- GJB5 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MMP2 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 30/501 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2
- MTCL1 | c.1160A>T p.N387I (on ENST00000306329 / NM_001378206.1; = p.N27I on NM_015210.4) | Missense Mutation (SNP) | VAF 14/512 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PANK2 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- TSPAN7 | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 32/627 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- ZNF687 | c.1036_1037del p.V346Nfs*8 | Frame Shift Del (DEL) | VAF 57/238 reads (24%) | called by mutect2, pindel, varscan2
- ANXA7 | c.1323G>A p.R441= (on ENST00000372919 / NM_001320880.2; = p.R419= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- DSP | c.5289C>T p.T1763= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- EGFR | c.2316C>T p.P772= | Silent (SNP) | VAF 65/222 reads (29%) | catalogued as COSV51863843, COSV51867531; called by muse, varscan2
- GTF2IRD1 | c.150C>T p.A50= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs1295161433; called by muse, mutect2, varscan2
- HIRA | c.1209G>A p.K403= | Silent (SNP) | VAF 35/397 reads (9%) | called by muse, mutect2
- HTR1A | c.666G>A p.A222= | Silent (SNP) | VAF 22/571 reads (4%) | catalogued as COSV60500938, COSV60502320; called by muse, mutect2
- LUZP2 | c.720C>A p.P240= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as COSV100421293; called by muse, mutect2
- MARCHF3 | c.273G>A p.G91= | Silent (SNP) | VAF 18/299 reads (6%) | catalogued as rs1443042924; called by muse, mutect2
- MAST3 | c.615G>A p.A205= | Silent (SNP) | VAF 15/242 reads (6%) | catalogued as rs781362233, COSV53222064; called by muse, mutect2
- TNXB | c.3336G>A p.E1112= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- VWA5B1 | c.423C>T p.V141= | Silent (SNP) | VAF 30/400 reads (8%) | called by muse, mutect2
- COPG1 | c.90+40A>T | Intron (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- FBXL21P | n.1298G>C | RNA (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- FHL2 | chr2:105399485 G>C | 5'Flank (SNP) | VAF 11/347 reads (3%) | catalogued as COSV104398386; called by muse, mutect2
- FRMD7 | c.-8C>A | 5'UTR (SNP) | VAF 20/388 reads (5%) | called by muse, mutect2
- PKLR | c.*19G>A | 3'UTR (SNP) | VAF 54/214 reads (25%) | called by muse, mutect2, varscan2
